Somatic mutation profile of tumor specimen TCGA-VS-A8Q8-01A (aliquot TCGA-VS-A8Q8-01A-11D-A37N-09) from TCGA case TCGA-VS-A8Q8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 26.2 years (9,571 days).
Specimen TCGA-VS-A8Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c51157a4-cc3d-4635-bbc2-272f638e4563.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8Q8-10A (Blood Derived Normal), aliquot TCGA-VS-A8Q8-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1349efa8-e545-45f4-98a8-c6c49d3ffb83

The open-access MAF lists 85 somatic variants for this specimen: 63 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 21, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs977070647, COSV100030406; called by muse, mutect2, varscan2
- AP4E1 | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV99957214; called by muse, mutect2, varscan2
- CAPRIN1 | c.1244C>G p.S415C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100404294, COSV58218043; called by muse, mutect2, varscan2
- CARF | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs200547023; called by muse, mutect2, varscan2
- CDK4 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.22); catalogued as COSV99226127; called by muse, mutect2, varscan2
- CHAT | c.1081T>A p.W361R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100340927; called by muse, mutect2, varscan2
- CLCN2 | c.2416-1G>A p.X806_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as rs949598785, COSV99659011; called by muse, mutect2, varscan2
- COL11A2 | c.4541G>A p.R1514H (on ENST00000341947 / NM_080680.3; = p.R1407H on NM_080679.2) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs756194499, COSV100554556; called by muse, mutect2, varscan2
- CORO1C | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1292307168, COSV54593770; called by muse, mutect2
- CRHR1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs929229913, COSV99524179; called by muse, mutect2, varscan2
- CSPG4 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756062229, COSV57890072; called by muse, mutect2, varscan2
- CUBN | c.3035C>G p.S1012C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100913575, COSV64709059; called by muse, mutect2, varscan2
- DCDC1 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV60850798; called by muse, mutect2, varscan2
- DDX11 | c.2449C>T p.Q817* (on ENST00000545668 / NM_152438.2; = p.Q767* on NM_004399.3) | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV52505596; called by muse, mutect2, varscan2
- DHRS9 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs766893376, COSV100513701; called by muse, mutect2, varscan2
- DNAJC14 | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 45/91 reads (49%) | catalogued as COSV99670866; called by muse, mutect2, varscan2
- FAM83G | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393900527, COSV100525533; called by muse, mutect2, varscan2
- FBXL20 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99234275; called by muse, mutect2, varscan2
- FGD6 | c.2758C>G p.Q920E | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100676824; called by muse, mutect2, varscan2
- GHSR | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53838555; called by muse, mutect2, varscan2
- HCFC1 | c.1370C>A p.T457N | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV100129931; called by muse, mutect2, varscan2
- HECTD4 | c.7028C>T p.A2343V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66398473; called by muse, mutect2
- HLA-B | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as rs41563914, CM1412127, COSV101318268; called by muse, mutect2
- HUWE1 | c.1934G>T p.R645M | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53358876, COSV99474287; called by muse, mutect2, varscan2
- IDE | c.2569C>A p.H857N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.085); catalogued as rs766038121, COSV99794433; called by muse, mutect2, varscan2
- IGLV4-69 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs779961811; called by muse, mutect2, varscan2
- IRX5 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV100316017; called by mutect2, varscan2
- KDELR3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs752256020, COSV53247310; called by muse, mutect2, varscan2
- KMT2C | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51285736; called by muse, mutect2, varscan2
- MAP3K15 | c.2235G>A p.M745I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV58830499; called by muse, mutect2, varscan2
- NPAS2 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs753351516, COSV59558190; called by muse, mutect2, varscan2
- NPAS4 | c.1314C>A p.F438L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV100215276; called by muse, mutect2, varscan2
- PBRM1 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs769010138, COSV99970840; called by muse, mutect2, varscan2
- PHEX | c.1018G>C p.V340L | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV101040041; called by muse, mutect2, varscan2
- PIEZO2 | c.7755G>T p.K2585N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV99555554; called by muse, mutect2, varscan2
- PIM2 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.18); catalogued as COSV99900556; called by muse, mutect2, varscan2
- PLCH1 | c.4343C>T p.S1448L (on ENST00000340059 / NM_001130960.2; = p.S1440L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.115); catalogued as COSV100398301; called by muse, mutect2, varscan2
- PRSS22 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs886349794, COSV99362011; called by muse, mutect2
- PTPRM | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100160626; called by muse, mutect2, varscan2
- RASA1 | c.2406G>A p.M802I | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57192907, COSV57198698; called by muse, mutect2, varscan2
- REM2 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as COSV99944772; called by muse, mutect2, varscan2
- RNF168 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100534881, COSV100535127; called by muse, mutect2, varscan2
- SBF1 | c.2058C>G p.F686L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100818044; called by muse, mutect2, varscan2
- SEMA6C | c.668-1G>A p.X223_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100501583; called by muse, mutect2, varscan2
- SFI1 | c.3619G>A p.E1207K (on ENST00000400288 / NM_001007467.3; = p.E1176K on NM_014775.4) | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV56717877, COSV99837407; called by muse, mutect2, varscan2
- SMG6 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs769291662, COSV99558772; called by muse, mutect2, varscan2
- STAT2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1565653029, COSV100029146; called by muse, mutect2, varscan2
- TAF7L | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 59/113 reads (52%) | catalogued as COSV61256651; called by muse, mutect2, varscan2
- TCN1 | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV99953478; called by muse, mutect2, varscan2
- TLE2 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as rs865946930, COSV99504691; called by muse, mutect2, varscan2
- TMLHE | c.767T>A p.V256E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100545114; called by muse, mutect2, varscan2
- VWA2 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs759923665, COSV100073989; called by muse, mutect2, varscan2
- WDR31 | c.136G>C p.E46Q (on ENST00000374193 / NM_001006615.3; = p.E45Q on NM_145241.5) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV100516600, COSV100516785; called by muse, mutect2, varscan2
- XDH | c.3106G>A p.G1036R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV101052474; called by muse, mutect2, varscan2
- ZBTB20 | c.1298C>T p.P433L (on ENST00000474710 / NM_001164342.2; = p.P360L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752208031, COSV100615311; called by muse, mutect2, varscan2
- ZDHHC20 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1186398168, COSV100203731; called by muse, mutect2, varscan2
- ZNF354B | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100483142; called by muse, mutect2, varscan2
- ZNF396 | c.346C>G p.H116D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV100108658; called by muse, mutect2, varscan2
- ZNF75D | c.491C>G p.A164G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100883699; called by muse, mutect2, varscan2
- ZNF781 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.035); catalogued as rs764576233, COSV100669381; called by muse, mutect2, varscan2
- ANKRD12 | c.2186dup p.N729Kfs*5 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | called by mutect2, varscan2
- ART1 | c.123G>T p.M41I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2
- FZD5 | c.1501dup p.W501Lfs*98 | Frame Shift Ins (INS) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- ALG1 | c.420C>G p.V140= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99276023; called by muse, mutect2, varscan2
- CDH4 | c.1995C>T p.T665= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100849682; called by muse, mutect2, varscan2
- DOCK4 | c.1461C>T p.F487= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as rs1402210223, COSV101455774; called by muse, mutect2
- KRT6B | c.75C>T p.L25= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs372179759; called by muse, varscan2
- LIMK2 | c.1674C>G p.L558= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV59181908, COSV59183074, COSV59184310; called by muse, mutect2
- MAP9 | c.1860G>A p.Q620= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV60905717; called by muse, mutect2, varscan2
- MAST3 | c.3426G>A p.P1142= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs763700922, COSV99446328; called by muse, mutect2, varscan2
- MCF2 | c.183G>T p.L61= | Silent (SNP) | VAF 87/154 reads (56%) | catalogued as COSV100645183; called by muse, mutect2, varscan2
- NR1I3 | c.24G>A p.L8= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs745711502, COSV100915917; called by muse, mutect2, varscan2
- NR2F2 | c.945C>G p.L315= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV101241182; called by muse, mutect2, varscan2
- OR1J4 | c.108G>A p.L36= | Silent (SNP) | VAF 41/133 reads (31%) | catalogued as COSV100534339; called by muse, mutect2, varscan2
- RTN4 | c.3327C>T p.L1109= (on ENST00000337526 / NM_020532.5; = p.L116= on NM_007008.3) | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100464003; called by muse, varscan2
- SPATA31A1 | c.1539T>A p.A513= | Silent (SNP) | VAF 202/395 reads (51%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5883C>T p.I1961= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs1382402782, COSV58953229; called by muse, mutect2, varscan2
- STAMBP | c.855C>T p.L285= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100277810; called by muse, mutect2, varscan2
- SYNE2 | c.15474G>A p.L5158= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs374906011; called by muse, mutect2, varscan2
- UBE4A | c.2694C>G p.V898= (on ENST00000252108 / NM_001204077.2; = p.V905= on NM_004788.4) | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV99348615; called by muse, mutect2, varscan2
- ULK3 | c.1068G>A p.L356= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as rs1567234531, COSV101475565; called by muse, mutect2, varscan2
- USF3 | c.3135A>G p.L1045= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100325822; called by muse, mutect2
- ZKSCAN5 | c.1068C>T p.L356= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV100460384; called by muse, mutect2, varscan2
- ZNF781 | c.420G>A p.L140= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV62200145; called by muse, mutect2, varscan2
- THSD4 | c.1016-70342G>T | Intron (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
